TCGA case TCGA-VV-A86M — Brain Lower Grade Glioma (TCGA-LGG)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Gliomas; Primary site: Brain; Tissue source site: John Wayne Cancer Center. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/284680b2-f961-402d-8740-e5f9e4fb4a98

Demographics
Sex at birth: female; Ethnicity: hispanic or latino; Country of residence at enrollment: United States; Age at index: 36 years; Vital status: Alive.

Diagnoses (1)
1. Astrocytoma, anaplastic: ICD-O-3 morphology code: 9401/3; ICD-10 code: C71.0; Tissue or organ of origin: Cerebrum; Site of resection or biopsy: Nervous system, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 36.8 years (13,453 days); Year of diagnosis: 2013; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 487 days (1.3 years); First symptom longest duration: >=181 Days; First symptom prior to diagnosis: Sensory Changes; Sites of involvement: Brain, Frontal lobe.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 92 days; Days to treatment end: 122 days; Treatment outcome: Stable Disease; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Days to treatment start: 122 days; Treatment outcome: Treatment Ongoing.
   Recorded as not given: Radiation Therapy, NOS to Head, Face or Neck, NOS, prior to diagnosis.

Follow-up (2 entries)
- Days to follow up: 214 days; Disease response: With Tumor.
- Days to follow up: 487 days (1.3 years); Disease response: Tumor Free.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Risk factors: Altered Mental Status / Seizure / Sensory Changes.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-VV-A86M-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 270 mg.
  Slide TCGA-VV-A86M-01A-01-TS1: Section location: Top; Percent tumor cells: 60; Percent tumor nuclei: 90; Percent normal cells: 10; Percent necrosis: 0; Percent stromal cells: 30; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-VV-A86M-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-VV-A86M-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Central nervous system; Histologic diagnosis: Astrocytoma; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; History ionizing radiation to head: No; Tumor status: With tumor; Tumor site: Supratentorial, Frontal Lobe; Supratentorial localization: Not listed in Medical Record; History seizures: Yes; History headaches: No; Symp changes mental status: Yes; Symp changes visual: No; Symp changes sensory: Yes; Symp changes motor movement: No; First symptom longest duration: > 181 Days; History asthma: No; Histor hay fever: No; History dust mold allergy: No; Allergy food diagnosis indicator: No; Allergy animals insects diagnosis indicator: No; New tumor event diagnosis indicator: No.
- Follow-up form: Lost to follow-up: No; New tumor event diagnosis indicator: No; Tumor status: Tumor free; Treatment outcome at TCGA followup: Complete Remission/Response.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 487 days; disease-specific survival: no event (censored), 487 days; progression-free interval: no event (censored), 487 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-VV-A86M-01A-11D-A36N-01): tumor purity 0.92, ploidy 1.96, whole-genome doublings 0.
